Surgical pathology report (de-identified scan), TCGA case TCGA-32-1970, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1970-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Brain tumor - FS
2. Brain tumor (glioblastoma)

GBM
CONTROL

CLINICAL DIAGNOSIS:

Brain tumor (glioblastoma)

TCGA-32-1970

GROSS DESCRIPTION:

1. Received fresh for frozen section is a 2.2 x 1.8 x 1.2 cm tan red portion of soft tissue. Serial sectioning reveals a tan red hemorrhagic surface. A smear is made and a representative section is frozen on one chuck.

FROZEN SECTION AND SMEAR PREP DIAGNOSIS:
GLIOBLASTOMA MULTIFORME.

The remainder of the specimen is submitted in cassettes 1B and 1C.

2. Received in formalin are multiple tan white hemorrhagic soft tissue fragments aggregating to 5.5 x 4 x 2.1 cm. Cut section reveals a tan hemorrhagic surface. Representative sections are submitted in cassettes 2A-2C.

MICROSCOPIC DESCRIPTION:

- 1, 2. Microscopic performed.

DIAGNOSIS:

1. BRAIN, BRAIN TUMOR, BIOPSIES:
HIGH GRADE MALIGNANT NEOPLASM CONSISTENT WITH GLIOBLASTOMA MULTIFORME,
ADDITIONAL STUDIES TO BE PERFORMED (SEE COMMENT BELOW).
2. BRAIN, "BRAIN TUMOR", RESECTION:
HIGH GRADE MALIGNANT NEOPLASM CONSISTENT WITH GLIOBLASTOMA MULTIFORME,
ADDITIONAL STUDIES TO BE PERFORMED (SEE COMMENT BELOW).

DIAGNOSIS:

COMMENT:

The overall findings in this case are certainly consistent with glioblastoma multiforme. Areas within the neoplasm have a differential which includes small blue cell tumor, as well as a small cell variant of glioblastoma. Sprinkled amongst the individual small neoplastic cells are tumor giant cells. In addition, there are foci which raise the possibility of oligodendroglial differentiation. Special stains will be performed and the case will be reviewed by [REDACTED] prior to submitting a final report.

Source: NCI Genomic Data Commons file e0f200a8-7afb-4740-94fe-df8fd58c8b88 (TCGA-32-1970.F55A66B9-6609-4CA0-BCAD-11C787F25598.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).